Somatic mutation profile of tumor specimen TCGA-DU-8163-01A (aliquot TCGA-DU-8163-01A-11D-2253-08) from TCGA case TCGA-DU-8163, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 29.6 years (10,824 days).
Specimen TCGA-DU-8163-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df936506-2ee4-4f43-b437-8f387dae69cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-8163-10A (Blood Derived Normal), aliquot TCGA-DU-8163-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00f2233f-46a8-4324-8674-9de35a27b5c2

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 25/97 reads (26%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 17/28 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATRX | c.6456T>G p.Y2152* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV64870577; called by muse, mutect2, varscan2
- ATRX | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV64869800; called by mutect2, varscan2
- GLI1 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs913592640, COSV57357429; called by muse, mutect2, varscan2
- MAPK7 | c.430C>G p.L144V | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55189102; called by muse, mutect2, varscan2
- MAPK7 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV55189107; called by muse, mutect2
- MYO18A | c.3410G>A p.G1137E | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1174967698, COSV62861982; called by muse, mutect2, varscan2
- OR10A4 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV65841655, COSV65841794; called by muse, mutect2
- XIRP1 | c.3755C>T p.A1252V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.888); catalogued as COSV61136676; called by muse, mutect2, varscan2
- CAPN2 | c.84C>G p.L28= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV54333630; called by muse, mutect2, varscan2
- CLCNKA | c.366A>G p.G122= | Silent (SNP) | VAF 63/466 reads (14%) | catalogued as COSV58890210; called by muse, mutect2, varscan2
- DLG1 | c.1836C>T p.I612= | Silent (SNP) | VAF 6/121 reads (5%) | catalogued as COSV58377124; called by muse, mutect2
- OR2T12 | c.165G>A p.R55= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs757174087, COSV58775847, COSV58778619; called by muse, mutect2, varscan2
